Somatic mutation profile of tumor specimen C3N-01028-02 (aliquot CPT0091050009) from CPTAC case C3N-01028, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.9 years (26,623 days).
Specimen C3N-01028-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) def2d197-ba6e-4afa-b263-8a639b86d97c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01028-31 (Blood Derived Normal), aliquot CPT0091160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34eb2e6c-dc19-46b3-8dbb-e9ac141d630b

The open-access MAF lists 826 somatic variants for this specimen: 565 protein-altering or splice-affecting, 153 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 488, Silent 153, Intron 64, Nonsense Mutation 39, Splice Site 15, 3'UTR 13, Frame Shift Del 13, RNA 13, 5'UTR 11, Splice Region 7, 5'Flank 6, Translation Start Site 1.

Variants (750 of 826; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs72554308, CM147679, CM941115; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RASA1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 54/202 reads (27%) | catalogued as rs137853218, CM081410, COSV57192495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.321C>A p.Y107* | Nonsense Mutation (SNP) | VAF 66/172 reads (38%) | hotspot (GDC flag); catalogued as rs770776262, CM154128, COSV52703111, COSV52765697, COSV53067955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 92/675 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773021659, COSV100068867; called by muse, mutect2, varscan2
- ACAN | c.1097del p.G366Vfs*10 | Frame Shift Del (DEL) | VAF 16/151 reads (11%) | catalogued as COSV61366998; called by mutect2, pindel, varscan2
- ADAD2 | c.1148C>G p.A383G (on ENST00000315906 / NM_001145400.2; = p.A465G on NM_139174.4) | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.38); catalogued as rs144157576; called by muse, mutect2, varscan2
- ADAMTS13 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs965535472; called by muse, mutect2, varscan2
- ADCY5 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1242756383; called by muse, mutect2
- ADGRA3 | c.3488G>T p.R1163L | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV51565862; called by muse, mutect2, varscan2
- AHCYL2 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as rs1262808452; called by muse, mutect2, varscan2
- AJUBA | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401205; called by muse, mutect2, varscan2
- ALDH9A1 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1220671498; called by muse, mutect2, varscan2
- ALKBH2 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV54358921; called by muse, mutect2, varscan2
- AOPEP | c.2325G>T p.M775I (on ENST00000375315 / NM_001193329.1; = p.M676I on NM_032823.5) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388491195, COSV99950334; called by muse, mutect2, varscan2
- AP3D1 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61429518; called by muse, mutect2, varscan2
- ARHGAP40 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs369941043; called by muse, mutect2, varscan2
- ARID1A | c.4101+1G>T p.X1367_splice | Splice Site (SNP) | VAF 45/181 reads (25%) | catalogued as COSV61375328, COSV61387522; called by muse, mutect2, varscan2
- ARSK | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.268); catalogued as rs770798168, COSV66170589; called by muse, mutect2, varscan2
- ASAH2 | c.1625+1G>A p.X542_splice | Splice Site (SNP) | VAF 29/339 reads (9%) | catalogued as rs1230411007; called by muse, mutect2
- ATG4A | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs763471998; called by muse, mutect2, varscan2
- ATP7A | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1057520234; ClinVar: likely benign; called by muse, mutect2, varscan2
- AXDND1 | c.1969C>G p.P657A | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV62649971; called by muse, mutect2, varscan2
- B3GLCT | c.1153G>T p.G385C | Missense Mutation (SNP) | VAF 150/525 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs922994461; called by muse, mutect2, varscan2
- BAZ2B | c.2050A>G p.M684V | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs141354239; called by muse, mutect2, varscan2
- BCL2L12 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55862309; called by muse, mutect2
- BLM | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV61925150; called by muse, mutect2
- BMX | c.1506G>T p.R502S | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59592783; called by muse, mutect2, varscan2
- BPNT1 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs897576181, COSV59041815; called by muse, mutect2, varscan2
- BTBD18 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs774642543; called by muse, mutect2, varscan2
- C20orf85 | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748551745, COSV100959338, COSV64519981; called by mutect2, varscan2
- C2CD2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764472590; called by muse, mutect2, varscan2
- CAPNS1 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.761); catalogued as COSV55822423, COSV55823124; called by muse, mutect2, varscan2
- CD200 | c.346A>G p.K116E (on ENST00000473539 / NM_001004196.3; = p.K91E on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/1122 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs769900158; called by muse, mutect2
- CD22 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 21/120 reads (18%) | catalogued as COSV50061668; called by muse, varscan2
- CDH18 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs965077471, COSV56960123; called by muse, mutect2, varscan2
- CEP170 | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 123/966 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs772579241, COSV60510437; called by muse, varscan2
- CNKSR3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs145122066; called by muse, mutect2, varscan2
- CNTN2 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100085310, COSV100085570; called by muse, mutect2, varscan2
- COL15A1 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1205991983; called by muse, mutect2, varscan2
- COL4A1 | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 116/479 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65432716; called by muse, mutect2, varscan2
- COL4A2 | c.2327T>C p.V776A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.754); catalogued as rs1157181000; called by muse, mutect2, varscan2
- CRACR2A | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs532414144, COSV61543550; called by muse, mutect2
- CRTAM | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1214209894, COSV57067966; called by muse, mutect2, varscan2
- CSMD1 | c.7197A>T p.Q2399H (on ENST00000520002; = p.Q2398H on NM_033225.6) | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs749303264; called by muse, mutect2, varscan2
- CTNNA2 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 220/728 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV63550267; called by muse, mutect2
- DCST1 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 71/323 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55062160; called by muse, mutect2, varscan2
- DNAH17 | c.10802C>A p.A3601D | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV67751464; called by muse, mutect2, varscan2
- DNAH2 | c.7899C>A p.F2633L | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs767788250; called by muse, mutect2, varscan2
- DNAH5 | c.8483G>T p.R2828L | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54252830; called by muse, mutect2, varscan2
- DNAH8 | c.6466C>T p.R2156* | Nonsense Mutation (SNP) | VAF 76/543 reads (14%) | catalogued as rs779286785; called by muse, mutect2, varscan2
- ECM2 | c.1855G>C p.D619H | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs763606251; called by muse, mutect2, varscan2
- EDDM3A | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs777138112; called by muse, varscan2
- EFNB2 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55363143; called by muse, mutect2, varscan2
- EHMT2 | c.3563G>A p.R1188H | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as rs547088463, COSV57666762; called by muse, mutect2, varscan2
- ENDOV | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 133/544 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as rs1419948226, COSV100108489; called by muse, mutect2, varscan2
- ENOX1 | c.1561G>T p.G521C | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV54910021; called by muse, mutect2, varscan2
- EPHA7 | c.2482del p.E828Kfs*19 | Frame Shift Del (DEL) | VAF 28/181 reads (15%) | catalogued as COSV65179212; called by mutect2, pindel, varscan2
- EPHB4 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.124); catalogued as rs371835903, COSV62270338; called by muse, mutect2, varscan2
- ERF | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756869919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64271458; called by muse, mutect2, varscan2
- FAM209A | c.272G>T p.R91L | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV54769417; called by muse, mutect2, varscan2
- FAM237A | c.434G>T p.R145M | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.938); catalogued as COSV71513349; called by muse, mutect2, varscan2
- FBXW9 | c.736G>A p.D246N (on ENST00000587955; = p.D256N on NM_032301.3) | Missense Mutation (SNP) | VAF 171/498 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as COSV66710000; called by muse, mutect2, varscan2
- FMO5 | c.1066G>T p.V356F | Missense Mutation (SNP) | VAF 101/482 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs138976736, COSV99567098; called by muse, mutect2, varscan2
- FMO5 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs781850993, COSV99567407; called by muse, mutect2, varscan2
- FRS2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.027); catalogued as rs759430968; called by muse, mutect2
- FSCB | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV61217837; called by muse, mutect2
- GAA | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 16/676 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128739; called by muse, mutect2
- GABRA1 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.403); catalogued as rs761617651, COSV50108276, COSV50110447; called by muse, mutect2, varscan2
- GJD3 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs971938573; called by muse, mutect2, varscan2
- GLYATL1 | c.821G>C p.R274P (on ENST00000317391 / NM_001354699.1; = p.R305P on NM_080661.4) | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as COSV100265476, COSV55611942; called by muse, mutect2, varscan2
- HCN3 | c.1778G>C p.G593A | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as COSV61361135; called by muse, mutect2, varscan2
- HDAC4 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.308); catalogued as rs754205133; called by muse, mutect2
- HEATR1 | c.5195A>C p.Q1732P | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1220258090; called by muse, varscan2
- HEATR6 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.7); catalogued as rs199943781; called by muse, mutect2, varscan2
- HERC1 | c.10588G>T p.A3530S | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1226668890; called by muse, mutect2, varscan2
- HIVEP2 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 70/322 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.292); catalogued as rs985905803; called by muse, mutect2, varscan2
- HMG20B | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as COSV53571837; called by muse, mutect2, varscan2
- IGHV1-45 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 131/440 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as rs377075520; called by muse, mutect2, varscan2
- IGHV4-39 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 160/550 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1289389553; called by muse, mutect2, varscan2
- IGKV1-12 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 54/1140 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1173879033; called by muse, mutect2
- IL13RA2 | c.332G>T p.W111L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54563901; called by muse, mutect2, varscan2
- IL2RA | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1247001197; called by muse, mutect2
- IL3RA | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100452219, COSV58430123, COSV58433847; called by muse, mutect2
- INHBE | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV56989416, COSV56989451; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.596G>T p.R199I | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV56442456; called by muse, mutect2, varscan2
- ITGA8 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 43/361 reads (12%) | catalogued as COSV65234752; called by muse, mutect2, varscan2
- ITPR2 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV54387884; called by muse, mutect2
- ITPRID1 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs546132367, COSV60079156; called by muse, mutect2, varscan2
- KCNH3 | c.2253C>G p.S751R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.944); catalogued as rs1350401785; called by muse, mutect2
- KCNJ16 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 110/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52257253; called by muse, mutect2, varscan2
- KCNJ4 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57856590; called by muse, mutect2
- KDR | c.2915C>G p.S972* | Nonsense Mutation (SNP) | VAF 39/263 reads (15%) | catalogued as COSV55771057; called by muse, mutect2, varscan2
- KEAP1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV50260398, COSV50261323, COSV50261936; called by muse, mutect2, varscan2
- KIR2DL4 | c.262C>A p.L88I (on ENST00000396284; = p.L49I on NM_001080770.2) | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60880552; called by muse, mutect2, varscan2
- KL | c.1123T>A p.L375M | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66308417; called by muse, mutect2, varscan2
- KLF5 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66615212; called by muse, mutect2, varscan2
- KRBA1 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560621826; called by muse, mutect2, varscan2
- KRI1 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 98/369 reads (27%) | catalogued as rs371694672; called by muse, mutect2, varscan2
- LARGE1 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.125); catalogued as COSV61665348; called by muse, mutect2, varscan2
- LBP | c.575T>A p.V192E | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV54139677; called by muse, mutect2, varscan2
- LDHC | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs200996269; called by muse, mutect2, varscan2
- LILRA2 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 64/690 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1390728656; called by muse, mutect2
- LIPG | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 25/630 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV54296371; called by muse, mutect2
- LRIT3 | c.1658G>C p.C553S | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59983688; called by muse, mutect2, varscan2
- LSM14A | c.856C>G p.R286G | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV70884958; called by muse, mutect2, varscan2
- MAN2C1 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV51231621; called by muse, mutect2, varscan2
- MAP4K3 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | catalogued as COSV55712006; called by muse, mutect2, varscan2
- MCHR1 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 101/425 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV50760980; called by muse, mutect2, varscan2
- MED12L | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV56393608, COSV56400645; called by muse, mutect2, varscan2
- MEIOC | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV63440161; called by muse, mutect2, varscan2
- MELK | c.264C>T p.Y88= | Splice Region (SNP) | VAF 272/401 reads (68%) | catalogued as rs142987107; called by muse, varscan2
- MMP13 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52824294, COSV99506849; called by muse, mutect2, varscan2
- MROH2B | c.2386G>T p.D796Y | Missense Mutation (SNP) | VAF 301/613 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs751187629, COSV101270903, COSV68181542; called by muse, mutect2, varscan2
- MTUS2 | c.2413A>G p.T805A | Missense Mutation (SNP) | VAF 97/297 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs770497798; called by muse, mutect2, varscan2
- MUC16 | c.38847G>T p.Q12949H | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV67449447; called by muse, mutect2, varscan2
- MXRA8 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.259); catalogued as COSV58510258; called by muse, mutect2
- MYCT1 | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 102/491 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs961581465; called by muse, mutect2, varscan2
- MYO18B | c.6311G>T p.G2104V | Missense Mutation (SNP) | VAF 114/480 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as rs563502950; called by muse, mutect2, varscan2
- NBEA | c.8661G>C p.E2887D | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as rs771970530; called by muse, mutect2, varscan2
- NBPF12 | c.641G>T p.S214I | Missense Mutation (SNP) | VAF 109/572 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.932); catalogued as rs1553885398; called by muse, mutect2, varscan2
- NCAM2 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV53054033; called by muse, mutect2, varscan2
- NFATC3 | c.3019G>T p.G1007W | Missense Mutation (SNP) | VAF 124/455 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV60477339; called by muse, mutect2, varscan2
- NLRP10 | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 37/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60778796; called by muse, mutect2, varscan2
- NNMT | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV55473919; called by muse, mutect2, varscan2
- NOTCH4 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs747566227, COSV100900805; called by muse, mutect2
- NPC1L1 | c.1802G>C p.R601P | Missense Mutation (SNP) | VAF 98/659 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as rs767641944; called by muse, mutect2, varscan2
- NPM1 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51551636; called by muse, mutect2, varscan2
- NR2C1 | c.214A>T p.T72S | Missense Mutation (SNP) | VAF 132/462 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV58008702; called by muse, varscan2
- OBSCN | c.7990C>G p.L2664V | Missense Mutation (SNP) | VAF 100/339 reads (29%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.856); catalogued as COSV52834853; called by muse, mutect2, varscan2
- OR1G1 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 149/481 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs968185987, COSV61030709; called by muse, mutect2, varscan2
- OR2L13 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 101/543 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs1322978288, COSV100813920, COSV63554288; called by muse, mutect2, varscan2
- OR2M4 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.576); catalogued as rs762833483; called by muse, mutect2, varscan2
- OR2W3 | c.643C>A p.L215M | Missense Mutation (SNP) | VAF 105/413 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64456706; called by muse, mutect2, varscan2
- OR4C12 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 79/381 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.084); catalogued as COSV58860739; called by muse, mutect2, varscan2
- OR4S1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353322852; called by muse, mutect2, varscan2
- OR5W2 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60616596, COSV60617281; called by muse, mutect2, varscan2
- OTOGL | c.5123T>C p.I1708T (on ENST00000547103; = p.I1699T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs367858052; called by muse, mutect2, varscan2
- PABPC4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 117/510 reads (23%) | catalogued as rs752944467, COSV63293361; called by muse, mutect2, varscan2
- PCDH10 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52097224; called by muse, mutect2
- PCDHA2 | c.1931G>C p.R644P | Missense Mutation (SNP) | VAF 82/243 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV65366738, COSV65370404; called by muse, mutect2, varscan2
- PCDHB9 | c.1839del p.L614Cfs*17 | Frame Shift Del (DEL) | VAF 114/524 reads (22%) | catalogued as COSV53383737; called by mutect2, pindel, varscan2
- PCSK6 | c.1892G>A p.G631D | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178390399; called by muse, mutect2, varscan2
- PDE6A | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 139/472 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547693426; called by muse, mutect2, varscan2
- PDZRN4 | c.2685C>A p.S895R (on ENST00000402685 / NM_001164595.2; = p.S637R on NM_013377.4) | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV54200320; called by muse, mutect2, varscan2
- PIGR | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732477; called by muse, varscan2
- POLR2D | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as rs1240409947; called by muse, mutect2, varscan2
- PPIP5K2 | c.2657G>T p.R886L | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782712968; called by muse, mutect2, varscan2
- PRRC2B | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV61936818; called by muse, mutect2, varscan2
- PTCHD3 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV71256373; called by muse, mutect2, varscan2
- PTPN5 | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100080208; called by muse, mutect2, varscan2
- PTPRT | c.3301C>T p.L1101F | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61972183; called by muse, mutect2, varscan2
- QSOX2 | c.1757G>A p.R586K | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1315193559; called by muse, mutect2, varscan2
- RAD23A | c.224T>A p.M75K | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV57129334; called by muse, mutect2, varscan2
- RGPD3 | c.5047C>A p.L1683I | Missense Mutation (SNP) | VAF 102/430 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.794); catalogued as rs1439683270, COSV58739942; called by muse, mutect2, varscan2
- RIMBP2 | c.2366T>C p.L789S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs765435561; called by muse, mutect2, varscan2
- RPGRIP1L | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 70/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50913082; called by muse, mutect2, varscan2
- RPRD1A | c.53A>G p.N18S | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs1389798761; called by muse, mutect2, varscan2
- RSPH3 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs760602630; called by muse, mutect2, varscan2
- SACS | c.9743G>T p.W3248L | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs778844692; called by muse, mutect2, varscan2
- SCN10A | c.390-1G>A p.X130_splice | Splice Site (SNP) | VAF 56/189 reads (30%) | catalogued as COSV71862559; called by muse, mutect2, varscan2
- SLC22A25 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1221621627; called by muse, mutect2, varscan2
- SNTG1 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV52459237; called by muse, mutect2, varscan2
- SYNE1 | c.8024G>T p.G2675V (on ENST00000367255 / NM_182961.4; = p.G2682V on NM_033071.3) | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1430196419; called by muse, mutect2, varscan2
- TAAR2 | c.422G>A p.R141K (on ENST00000367931 / NM_001033080.1; = p.R96K on NM_014626.3) | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51579591; called by muse, mutect2, varscan2
- TAAR9 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763335689; called by muse, mutect2, varscan2
- TAF4 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99434557; called by muse, mutect2, varscan2
- TBC1D22B | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs775335389; called by muse, mutect2, varscan2
- TERT | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 222/613 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.175); catalogued as COSV57204860; called by muse, mutect2, varscan2
- TLE2 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1485049038; called by muse, mutect2
- TMEM132D | c.1727T>C p.M576T | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as rs372456663; called by muse, mutect2, varscan2
- TMEM150B | c.550T>A p.C184S | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58594056; called by muse, mutect2, varscan2
- TMPPE | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56563394; called by muse, mutect2, varscan2
- TNRC6C | c.3971-1G>T p.X1324_splice | Splice Site (SNP) | VAF 54/184 reads (29%) | catalogued as COSV100049585; called by muse, varscan2
- TOR1AIP1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs147648930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAP1 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1386010548; called by muse, mutect2, varscan2
- TRDN | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV62121224; called by muse, varscan2
- TRIM2 | c.1687G>A p.D563N (on ENST00000437508; = p.D590N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs1023492892, COSV58630941; called by muse, mutect2, varscan2
- TRIP6 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs772986111; called by muse, mutect2, varscan2
- TRPC7 | c.1884C>A p.F628L | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61456203; called by muse, mutect2, varscan2
- TTN | c.2643C>A p.F881L (on ENST00000591111; = p.F835L on NM_003319.4) | Missense Mutation (SNP) | VAF 99/656 reads (15%) | PolyPhen benign (0.415); catalogued as COSV100600393, COSV60325558; called by muse, mutect2, varscan2
- TTYH1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 93/369 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs1169708186; called by muse, mutect2, varscan2
- TUBA4A | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778571547, COSV50279588; called by muse, mutect2, varscan2
- USH2A | c.14101G>T p.E4701* | Nonsense Mutation (SNP) | VAF 59/346 reads (17%) | catalogued as COSV56431603; called by muse, mutect2, varscan2
- VPS13A | c.33G>C p.L11F | Missense Mutation (SNP) | VAF 135/447 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62431891; called by muse, mutect2, varscan2
- WDFY4 | c.6310A>T p.K2104* | Nonsense Mutation (SNP) | VAF 38/168 reads (23%) | catalogued as COSV55426803; called by muse, mutect2, varscan2
- WDR17 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV54585428; called by muse, mutect2, varscan2
- ZFAT | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64740644, COSV64741702; called by muse, mutect2, varscan2
- ZFYVE26 | c.4322A>T p.D1441V | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.197); catalogued as COSV61324616; called by muse, mutect2
- ZKSCAN2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs780366560; called by muse, mutect2, varscan2
- ZNF569 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 43/199 reads (22%) | catalogued as COSV57593809; called by muse, mutect2, varscan2
- ZNHIT1 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758030402, COSV59312572; called by muse, mutect2, varscan2
- ZSCAN1 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV56602528; called by muse, mutect2, varscan2
- ZSCAN5A | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as rs1333412548, COSV54230066; called by muse, mutect2, varscan2
- ABAT | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 152/572 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCF3 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 74/472 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- AC011455.2 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 69/552 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC013477.1 | c.2180A>T p.K727I | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSL3 | c.2126A>T p.Y709F | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ADA2 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.1829G>A p.C610Y | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS7 | c.2305A>T p.T769S | Missense Mutation (SNP) | VAF 173/652 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADGB | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, varscan2
- ADHFE1 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADIG | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 59/311 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- AFG1L | c.648G>A p.Q216= | Splice Region (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- AGO1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- AJUBA | c.1160G>C p.C387S | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKR7A2 | c.911A>G p.Q304R | Missense Mutation (SNP) | VAF 138/501 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ALMS1 | c.2632A>G p.S878G | Missense Mutation (SNP) | VAF 78/373 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AMER2 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AMER3 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- AMPH | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AMY2B | c.1191G>C p.W397C | Missense Mutation (SNP) | VAF 58/395 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO1 | c.2335A>T p.R779* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- ANO7 | c.1397C>A p.P466H (on ENST00000274979; = p.P412H on NM_001370694.2) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AOPEP | c.1933G>C p.E645Q (on ENST00000375315 / NM_001193329.1; = p.E546Q on NM_032823.5) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- APBB2 | c.950G>T p.W317L (on ENST00000295974 / NM_001166050.2; = p.W318L on NM_004307.2) | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- APH1B | c.422T>C p.L141S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- AQP12A | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, varscan2
- ARFGEF1 | c.2619C>G p.I873M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARL6IP4 | c.749A>T p.Q250L (on ENST00000315580 / NM_018694.3; = p.Q231L on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, varscan2
- ARMCX2 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ARX | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, varscan2
- ASB10 | c.865G>A p.A289T (on ENST00000420175 / NM_001142459.2; = p.A274T on NM_080871.4) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ASPM | c.3744G>T p.V1248= | Splice Region (SNP) | VAF 105/407 reads (26%) | called by mutect2, varscan2
- ASXL2 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 94/413 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ASXL3 | c.6196A>T p.R2066* | Nonsense Mutation (SNP) | VAF 162/582 reads (28%) | called by muse, mutect2, varscan2
- ATAT1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- B4GALNT1 | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- BEST3 | c.1418G>T p.R473M | Missense Mutation (SNP) | VAF 101/351 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- BMP2 | c.997C>G p.L333V | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BPIFB4 | c.1289T>A p.V430E | Missense Mutation (SNP) | VAF 82/448 reads (18%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- BRD2 | c.1669A>G p.K557E | Missense Mutation (SNP) | VAF 69/482 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BRD7 | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- BRIP1 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 186/803 reads (23%) | called by muse, mutect2, varscan2
- BVES | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- C19orf18 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf38 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 93/322 reads (29%) | called by muse, mutect2, varscan2
- C4BPA | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CACNA1A | c.6319C>A p.Q2107K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, varscan2
- CALHM5 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- CAMKK1 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CANX | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- CBLC | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CCDC14 | c.697G>T p.V233F (on ENST00000488653; = p.V185F on NM_022757.5) | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC168 | c.16375G>T p.V5459L | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC3 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 94/287 reads (33%) | called by muse, mutect2, varscan2
- CD248 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDH12 | c.1256+1G>T p.X419_splice | Splice Site (SNP) | VAF 42/278 reads (15%) | called by muse, varscan2
- CDH6 | c.2087C>G p.A696G | Missense Mutation (SNP) | VAF 95/477 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CFTR | c.2959C>G p.L987V | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CHST10 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 121/528 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CILP | c.2391C>A p.D797E | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2
- CLCN1 | c.2172+2T>A p.X724_splice | Splice Site (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- CLDN5 | c.325G>C p.A109P (on ENST00000618236 / NM_001363066.2; = p.A194P on NM_003277.4) | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- CLSTN2 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 87/358 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CNKSR3 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNOT4 | c.2083A>T p.R695* (on ENST00000541284 / NM_001190850.1; = p.R621* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 43/297 reads (14%) | called by muse, mutect2, varscan2
- CNOT4 | c.1644G>T p.K548N (on ENST00000315544 / NM_001190848.1; = p.K545N on NM_001008225.2) | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTLN | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- COBL | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- COL22A1 | c.4562del p.G1521Vfs*15 | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- COL22A1 | c.1577A>T p.Q526L | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- COL2A1 | c.1795C>G p.P599A | Missense Mutation (SNP) | VAF 143/562 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- COL6A3 | c.8792G>A p.R2931K | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A6 | c.1082C>G p.T361S | Missense Mutation (SNP) | VAF 69/360 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COL7A1 | c.8261G>T p.G2754V | Missense Mutation (SNP) | VAF 165/463 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPG1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CPS1 | c.4334T>A p.F1445Y | Missense Mutation (SNP) | VAF 80/500 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRACDL | c.2452G>C p.A818P | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CRACR2A | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CRYBB1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 101/546 reads (18%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.1053G>C p.M351I | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, varscan2
- CTNNA2 | c.2710G>T p.V904L (on ENST00000402739 / NM_001282597.3; = p.V856L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CTU2 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CUBN | c.4279A>T p.S1427C | Missense Mutation (SNP) | VAF 57/519 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DAGLA | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 15/479 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- DAXX | c.687G>T p.K229N | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCD | c.263T>A p.V88D | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); called by muse, mutect2
- DCDC1 | c.4172G>T p.R1391L (on ENST00000597505 / NM_001367979.1; = p.R498L on NM_020869.3) | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- DCHS1 | c.2786T>A p.V929D | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2
- DCHS2 | c.1661C>G p.P554R | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL2 | c.8107G>C p.E2703Q | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- DNAH11 | c.3278A>T p.Y1093F | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- DNAH17 | c.4208A>G p.K1403R | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DNAH6 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNAH6 | c.5035T>A p.S1679T | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH9 | c.9146G>A p.R3049K | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAJC21 | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 57/368 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DNM3 | c.2480C>A p.S827Y (on ENST00000355305 / NM_001350206.2; = p.S821Y on NM_015569.5) | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DOCK4 | c.1373del p.V458Gfs*14 | Frame Shift Del (DEL) | VAF 28/291 reads (10%) | called by mutect2, pindel
- DOCK7 | c.816C>A p.L272= | Splice Region (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- DSG3 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 135/625 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- DYNC1H1 | c.10006A>T p.K3336* | Nonsense Mutation (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- DYNC2H1 | c.4000G>T p.E1334* | Nonsense Mutation (SNP) | VAF 116/438 reads (26%) | called by muse, mutect2, varscan2
- ELL | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- EMILIN1 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- EP300 | c.4229G>T p.R1410M | Missense Mutation (SNP) | VAF 116/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- EPHB6 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 121/528 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPRS1 | c.3853A>G p.M1285V | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ERMARD | c.1040T>G p.F347C | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ESS2 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ETNPPL | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVC2 | c.1785G>T p.R595S | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- EVI5L | c.2141A>T p.D714V | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- EXOC4 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- F5 | c.5507C>A p.S1836Y | Missense Mutation (SNP) | VAF 156/596 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM131B | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 62/240 reads (26%) | called by muse, varscan2
- FAM187B | c.425T>A p.F142Y | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FAM234A | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 86/377 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM237A | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- FAM47E | c.1171A>T p.T391S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FAM71E2 | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2
- FBH1 | c.2794A>G p.T932A (on ENST00000362091 / NM_178150.3; = p.T983A on NM_032807.4) | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- FBRSL1 | c.2803G>T p.G935C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- FBXL17 | c.1280A>T p.D427V | Missense Mutation (SNP) | VAF 89/306 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FBXL4 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- FCGR3A | c.106A>T p.R36W | Missense Mutation (SNP) | VAF 177/1045 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FECH | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FLT3 | c.1769T>G p.F590C | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC7 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 118/390 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.253); called by muse, varscan2
- FOXC2 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 99/573 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRMPD4 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GAL3ST2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- GALNT18 | c.84C>A p.Y28* | Nonsense Mutation (SNP) | VAF 89/377 reads (24%) | called by muse, mutect2, varscan2
- GALNT3 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- GAS2L1 | c.839-1G>A p.X280_splice | Splice Site (SNP) | VAF 49/183 reads (27%) | called by muse, mutect2, varscan2
- GCFC2 | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GFPT2 | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFRAL | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIPR | c.833G>A p.R278K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GLYATL3 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1757C>A p.A586D | Missense Mutation (SNP) | VAF 52/836 reads (6%) | SIFT tolerated, low confidence (1); called by muse, mutect2
- GOT1L1 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GPI | c.857T>A p.L286Q | Missense Mutation (SNP) | VAF 56/599 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- GPR12 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR65 | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 97/394 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- GPR88 | c.59T>A p.L20H | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIN2A | c.4239del p.R1414Gfs*32 | Frame Shift Del (DEL) | VAF 111/642 reads (17%) | called by mutect2, pindel, varscan2
- HAUS6 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HECA | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HECTD4 | c.4639C>G p.Q1547E | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HELZ2 | c.3149A>G p.E1050G (on ENST00000467148 / NM_001037335.2; = p.E481G on NM_033405.3) | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPHL1 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEPHL1 | c.3389C>A p.T1130K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); called by mutect2, varscan2
- HIVEP2 | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HK3 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNMT | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2
- IBTK | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IFT57 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.11); called by muse, mutect2
- IGBP1P2 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- IGHV3-13 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- IGSF1 | c.3701C>G p.P1234R | Missense Mutation (SNP) | VAF 78/141 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF3 | c.3207G>C p.Q1069H (on ENST00000369486 / NM_001007237.3; = p.Q1089H on NM_001542.4) | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IL12RB1 | c.1950G>T p.L650F | Missense Mutation (SNP) | VAF 184/602 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); called by muse, varscan2
- IL17RA | c.1273G>T p.V425F | Missense Mutation (SNP) | VAF 108/561 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- IL17RA | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 186/784 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- IL20RA | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- IL21R | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- IL2RA | c.725C>G p.A242G | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- INTS13 | c.2120G>T p.*707Lext*4 | Nonstop Mutation (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- IPO8 | c.377A>T p.H126L | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- JAK1 | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KARS1 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 193/804 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- KCNA5 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- KCNIP2 | c.305T>A p.F102Y (on ENST00000356640 / NM_173191.3; = p.F117Y on NM_014591.5) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- KCNK3 | c.371T>G p.M124R | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KDM4B | c.1949A>G p.D650G | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIF19 | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIFBP | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIFC3 | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KLHDC7B | c.687T>G p.F229L (on ENST00000395676; = p.F870L on NM_138433.5) | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLHL36 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KMT2C | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KNL1 | c.3197C>A p.A1066D (on ENST00000346991 / NM_170589.5; = p.A1040D on NM_144508.5) | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.107); called by mutect2, varscan2
- KRT23 | c.397-1G>C p.X133_splice | Splice Site (SNP) | VAF 54/215 reads (25%) | called by muse, mutect2, varscan2
- KRTAP1-3 | c.220A>C p.S74R | Missense Mutation (SNP) | VAF 179/863 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- LAMA4 | c.1676C>T p.S559L (on ENST00000230538 / NM_001105206.3; = p.S552L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LATS1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 79/369 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCT | c.4999del p.E1667Rfs*56 | Frame Shift Del (DEL) | VAF 98/575 reads (17%) | called by mutect2, pindel, varscan2
- LCT | c.4237C>A p.P1413T | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LEMD3 | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 143/502 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHFPL3 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 82/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LILRB3 | c.1873T>A p.S625T (on ENST00000346401; = p.S613T on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/468 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LIPF | c.1106T>G p.F369C | Missense Mutation (SNP) | VAF 133/445 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LPAR6 | c.997T>G p.L333V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LPCAT4 | c.176T>G p.F59C | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- LRAT | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRBA | c.6511G>A p.A2171T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LRCH3 | c.1329-1G>T p.X443_splice | Splice Site (SNP) | VAF 44/239 reads (18%) | called by mutect2, varscan2
- LRP5 | c.984G>C p.Q328H | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- LRRC7 | c.4294C>T p.Q1432* (on ENST00000651989 / NM_001370785.2; = p.Q1352* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 87/297 reads (29%) | called by muse, mutect2, varscan2
- LUZP1 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- LY6G5B | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYST | c.3713-1G>A p.X1238_splice | Splice Site (SNP) | VAF 40/322 reads (12%) | called by muse, varscan2
- MAGEC1 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 70/476 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MANBA | c.2129A>G p.Q710R (on ENST00000642252; = p.Q664R on NM_005908.4) | Missense Mutation (SNP) | VAF 35/609 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- MANEAL | c.1076G>A p.G359E (on ENST00000373045 / NM_001113482.1; = p.G137E on NM_152496.2) | Missense Mutation (SNP) | VAF 229/459 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2 | c.5136G>T p.K1712N | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MCM4 | c.76A>T p.S26C | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- MEGF11 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS1 | c.935C>G p.T312R | Missense Mutation (SNP) | VAF 93/485 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKS1 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 175/745 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MN1 | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MORC1 | c.65+2T>A p.X22_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- MOXD1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- MYH1 | c.4039C>A p.L1347M | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MYO1G | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1L | c.1724C>A p.A575D | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAE1 | c.54-1G>A p.X18_splice | Splice Site (SNP) | VAF 39/143 reads (27%) | called by muse, mutect2, varscan2
- NBPF11 | c.2428A>C p.M810L | Missense Mutation (SNP) | VAF 79/662 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NCK2 | c.310A>T p.S104C | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NEUROD6 | c.194G>T p.R65M | Missense Mutation (SNP) | VAF 60/491 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); called by mutect2, varscan2
- NEXMIF | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NF1 | c.6565C>T p.P2189S (on ENST00000358273 / NM_001042492.3; = p.P2168S on NM_000267.3) | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NF1 | c.6751_6753delinsTT p.V2251Ffs*14 (on ENST00000358273 / NM_001042492.3; = p.V2230Ffs*14 on NM_000267.3) | Frame Shift Del (DEL) | VAF 63/522 reads (12%) | called by pindel, varscan2*
- NOD2 | c.1524del p.T509Pfs*8 | Frame Shift Del (DEL) | VAF 39/297 reads (13%) | called by mutect2, pindel, varscan2
- NOP53 | c.1296+6C>T | Splice Region (SNP) | VAF 51/198 reads (26%) | called by muse, mutect2, varscan2
- NOTCH3 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 146/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH4 | c.5243G>T p.R1748L | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NOTO | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 110/529 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPC1L1 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPFFR2 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN1 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR14J1 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- OR1C1 | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OR4C13 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR51E1 | c.515G>A p.C172Y | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR5D14 | c.624T>A p.N208K | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- OR8J3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL6 | c.449T>G p.I150R | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OSMR | c.2206G>T p.E736* | Nonsense Mutation (SNP) | VAF 75/490 reads (15%) | called by muse, mutect2, varscan2
- PAAF1 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- PARP15 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 130/530 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PCDHB10 | c.1839del p.L614Cfs*17 | Frame Shift Del (DEL) | VAF 54/687 reads (8%) | called by mutect2, pindel
- PDE2A | c.1030G>T p.V344L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PFKFB1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 55/124 reads (44%) | PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PGAM2 | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 98/821 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PHAX | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PHF21A | c.1235G>A p.S412N (on ENST00000418153 / NM_001101802.3; = p.S413N on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/513 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PI4KA | c.3997G>T p.G1333C | Missense Mutation (SNP) | VAF 75/448 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PIP5K1A | c.910C>G p.L304V (on ENST00000368888 / NM_001135638.2; = p.L291V on NM_003557.3) | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PLA2G12B | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PLCL1 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 120/497 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PLEKHA6 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PNLIPRP2 | c.768T>A p.C256* | Nonsense Mutation (SNP) | VAF 80/221 reads (36%) | called by muse, mutect2, varscan2
- PPDPF | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPFIA1 | c.3139G>T p.D1047Y | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PRKCG | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 63/510 reads (12%) | called by muse, mutect2, varscan2
- PRLR | c.1396A>C p.K466Q | Missense Mutation (SNP) | VAF 250/745 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PRODH2 | c.284G>T p.W95L (on ENST00000301175; = p.W19L on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PROX1 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PRRC2C | c.5034G>C p.L1678F (on ENST00000367742; = p.L1676F on NM_015172.4) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PRSS22 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PRUNE1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 109/484 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PSMB10 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2
- PTCHD3 | c.620A>C p.N207T | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PTPRD | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 26/557 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2
- PTPRZ1 | c.1653G>T p.M551I | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRZ1 | c.5515C>T p.Q1839* | Nonsense Mutation (SNP) | VAF 72/229 reads (31%) | called by muse, mutect2, varscan2
- RAB24 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RAPGEF2 | c.3963G>T p.Q1321H | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RASIP1 | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RBM15B | c.697A>G p.S233G | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBP3 | c.3682G>T p.E1228* | Nonsense Mutation (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- RIF1 | c.4514del p.K1505Rfs*18 | Frame Shift Del (DEL) | VAF 26/196 reads (13%) | called by mutect2, varscan2
- RIMBP3 | c.3535G>C p.A1179P | Missense Mutation (SNP) | VAF 70/720 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RIMS2 | c.3730G>C p.A1244P | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF17 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROCK1 | c.2020A>G p.N674D | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPL3 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RSPO1 | c.677A>T p.N226I | Missense Mutation (SNP) | VAF 123/606 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RUNX1 | c.914_920del p.D305Afs*260 (on ENST00000344691 / NM_001001890.3; = p.D332Afs*260 on NM_001754.5) | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | called by mutect2, pindel, varscan2
- SCN1A | c.4118T>G p.F1373C (on ENST00000303395 / NM_001202435.3; = p.F1362C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCNN1A | c.1864A>G p.M622V | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC11C | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA6C | c.2776G>T p.G926C | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SENP2 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- SHANK1 | c.6181A>C p.I2061L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHCBP1L | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SIGLEC6 | c.1274A>T p.H425L | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- SLC12A6 | c.877-1G>T p.X293_splice (on ENST00000354181 / NM_001365088.1; = p.X242_splice on NM_005135.2) | Splice Site (SNP) | VAF 48/355 reads (14%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1346G>A p.C449Y | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- SLC16A4 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC25A17 | c.838A>T p.T280S | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLC25A3 | c.-4-7C>G | Splice Region (SNP) | VAF 98/459 reads (21%) | called by muse, varscan2
- SLC25A51 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC26A4 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 57/442 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC26A9 | c.1836C>A p.N612K | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SLC27A2 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 114/413 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLC39A2 | c.137G>T p.R46I | Missense Mutation (SNP) | VAF 97/381 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SLC39A6 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 210/787 reads (27%) | called by muse, mutect2, varscan2
- SLC4A10 | c.2969A>T p.Q990L (on ENST00000446997 / NM_001354461.2; = p.Q960L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/390 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC4A1AP | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SLC5A6 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9C1 | c.1386T>A p.D462E | Missense Mutation (SNP) | VAF 27/570 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMCP | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 74/398 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMCP | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 76/398 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMIM8 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMOC2 | c.601G>T p.V201F (on ENST00000356284 / NM_001166412.2; = p.V212F on NM_022138.3) | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2
- SP2 | c.704G>C p.S235T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.017); called by muse, mutect2
- SP8 | c.935C>T p.S312L (on ENST00000361443 / NM_198956.4; = p.S330L on NM_182700.6) | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPACA1 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- SPDEF | c.245G>C p.S82T | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM1 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SSPOP | n.11222C>A | Splice Region (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- STK19 | c.986G>T p.R329L (on ENST00000375333 / NM_032454.1; = p.R325L on NM_004197.1) | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNPO2 | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- TAP1 | c.1799A>T p.N600I | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- TAP2 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TASOR2 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TEX55 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.25); called by muse, mutect2
- THOC5 | c.1489+2T>G p.X497_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- TIGIT | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 94/1062 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- TMC2 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TMCC1 | c.234A>C p.E78D | Missense Mutation (SNP) | VAF 46/594 reads (8%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- TMX2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TNFRSF19 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNN | c.1153T>A p.Y385N | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TNR | c.3418C>A p.Q1140K | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TNRC18 | c.2669del p.R890Pfs*48 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel
- TOMM70 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TPBGL | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TPR | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TRAV17 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- TRIM24 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRIM37 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 92/486 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TRIM51 | c.38T>A p.L13H | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRIM60 | c.968A>T p.K323I | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TRIM64C | c.487A>T p.S163C | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TRPM8 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTC21B | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 106/447 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TTN | c.65383C>A p.P21795T (on ENST00000591111; = p.P14371T on NM_003319.4) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.2644C>A p.P882T (on ENST00000591111; = p.P836T on NM_003319.4) | Missense Mutation (SNP) | VAF 100/660 reads (15%) | PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TXNRD3 | c.1761C>G p.F587L (on ENST00000523403 / NM_001173513.2; = p.F623L on NM_052883.2) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- UBTF | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2, varscan2
- USP25 | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- VAC14 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSTM2B | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 56/509 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- WASHC2A | c.3937C>G p.R1313G | Missense Mutation (SNP) | VAF 82/1035 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- WDR17 | c.610G>C p.G204R | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR19 | c.395T>G p.I132S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WDR53 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 109/540 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR72 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR76 | c.928A>G p.K310E | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPC | c.1828dup p.Y610Lfs*19 | Frame Shift Ins (INS) | VAF 36/126 reads (29%) | called by mutect2, pindel
- XPO6 | c.832G>C p.A278P | Missense Mutation (SNP) | VAF 88/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBED6CL | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ZBTB20 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- ZDBF2 | c.5260C>G p.P1754A | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, varscan2
- ZEB2 | c.1789C>A p.H597N | Missense Mutation (SNP) | VAF 108/438 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZFR2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF17 | c.1497A>C p.E499D | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF222 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF287 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF333 | c.809C>G p.S270* | Nonsense Mutation (SNP) | VAF 76/254 reads (30%) | called by muse, mutect2, varscan2
- ZNF431 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 37/432 reads (9%) | called by muse, mutect2
- ZNF492 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF587B | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 35/268 reads (13%) | called by muse, mutect2, varscan2
- ZNF607 | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF674 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- ZNF768 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 39/308 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF878 | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ABCB5 | c.915T>A p.A305= | Silent (SNP) | VAF 54/269 reads (20%) | called by muse, mutect2, varscan2
- ABHD8 | c.48G>T p.T16= | Silent (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- ACAN | c.2349C>A p.A783= | Silent (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- ADAM33 | c.405G>T p.G135= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV62936936; called by muse, mutect2, varscan2
- AHSG | c.591C>G p.T197= | Silent (SNP) | VAF 92/227 reads (41%) | called by muse, mutect2, varscan2
- AKR7L | c.528G>A p.R176= | Silent (SNP) | VAF 100/305 reads (33%) | called by muse, mutect2, varscan2
- APLP1 | c.1470G>T p.L490= | Silent (SNP) | VAF 103/341 reads (30%) | called by muse, mutect2, varscan2
- APOB | c.5385T>C p.T1795= | Silent (SNP) | VAF 95/407 reads (23%) | called by muse, mutect2, varscan2
- ARPP21 | c.1440C>A p.I480= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV51810679; called by muse, mutect2, varscan2
- ARX | c.834T>C p.A278= | Silent (SNP) | VAF 63/155 reads (41%) | called by muse, mutect2, varscan2
- ASPA | c.375T>C p.T125= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as rs776006406; called by muse, mutect2, varscan2
- ASXL3 | c.582G>T p.S194= | Silent (SNP) | VAF 60/182 reads (33%) | called by muse, mutect2, varscan2
- ATP2C2 | c.975G>T p.T325= | Silent (SNP) | VAF 50/341 reads (15%) | catalogued as COSV52294323, COSV52298682; called by muse, mutect2, varscan2
- ATP9A | c.3063G>C p.L1021= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- B3GLCT | c.1152T>C p.T384= | Silent (SNP) | VAF 148/522 reads (28%) | called by muse, mutect2, varscan2
- BAZ2A | c.378C>A p.I126= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as COSV51634897; called by muse, mutect2
- BIN2 | c.574C>T p.L192= | Silent (SNP) | VAF 63/288 reads (22%) | called by muse, mutect2, varscan2
- BMS1 | c.2991G>A p.Q997= | Silent (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- C16orf96 | c.3228T>C p.S1076= | Silent (SNP) | VAF 53/339 reads (16%) | called by muse, mutect2, varscan2
- CACNA1S | c.3981G>A p.E1327= | Silent (SNP) | VAF 51/394 reads (13%) | catalogued as COSV100755030; called by muse, mutect2, varscan2
- CCDC18 | c.3936A>G p.E1312= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV100160158; called by muse, mutect2, varscan2
- CHRM2 | c.1179G>T p.L393= | Silent (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- CHRNA2 | c.1461T>A p.S487= | Silent (SNP) | VAF 54/183 reads (30%) | called by muse, mutect2, varscan2
- COBL | c.2340G>T p.L780= | Silent (SNP) | VAF 50/241 reads (21%) | catalogued as COSV99473562; called by muse, mutect2, varscan2
- COPA | c.1911G>A p.V637= | Silent (SNP) | VAF 63/281 reads (22%) | called by muse, mutect2, varscan2
- CPOX | c.132C>A p.A44= | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- CPT2 | c.1488C>T p.H496= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as rs139321501; called by muse, mutect2, varscan2
- CREBBP | c.7161C>A p.L2387= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV52129369; called by muse, mutect2, varscan2
- CRPPA | c.400C>T p.L134= | Silent (SNP) | VAF 67/463 reads (14%) | called by muse, varscan2
- CSMD2 | c.7884C>T p.Y2628= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CTCF | c.2181G>T p.R727= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, varscan2
- CUL3 | c.1740A>T p.A580= | Silent (SNP) | VAF 47/244 reads (19%) | called by muse, mutect2, varscan2
- DACH1 | c.1566G>T p.R522= (on ENST00000619232 / NM_001366712.1; = p.R470= on NM_080759.6) | Silent (SNP) | VAF 51/211 reads (24%) | called by muse, mutect2, varscan2
- DDX54 | c.2085G>T p.L695= | Silent (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- DEDD | c.855G>C p.V285= | Silent (SNP) | VAF 85/512 reads (17%) | called by muse, mutect2, varscan2
- DLC1 | c.2127G>A p.K709= (on ENST00000276297 / NM_001348081.2; = p.K272= on NM_006094.5) | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- DNAH5 | c.11262A>G p.K3754= | Silent (SNP) | VAF 125/695 reads (18%) | called by muse, mutect2, varscan2
- DNAJC12 | c.426A>G p.S142= | Silent (SNP) | VAF 62/226 reads (27%) | called by muse, mutect2, varscan2
- DYNC1LI1 | c.1245T>C p.S415= | Silent (SNP) | VAF 62/195 reads (32%) | called by muse, mutect2, varscan2
- EFS | c.966C>G p.P322= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2
- EMILIN1 | c.138C>G p.A46= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as COSV66694660; called by muse, mutect2, varscan2
- ENTPD4 | c.1041A>G p.Q347= | Silent (SNP) | VAF 57/145 reads (39%) | called by muse, mutect2, varscan2
- EPB41L1 | c.645G>T p.L215= | Silent (SNP) | VAF 172/721 reads (24%) | called by muse, mutect2, varscan2
- ESYT1 | c.588C>T p.V196= | Silent (SNP) | VAF 109/409 reads (27%) | catalogued as COSV99919932; called by muse, mutect2, varscan2
- FAP | c.819G>T p.A273= | Silent (SNP) | VAF 53/282 reads (19%) | catalogued as rs150058882; called by muse, mutect2, varscan2
- FAT4 | c.5386C>T p.L1796= | Silent (SNP) | VAF 93/337 reads (28%) | called by muse, mutect2, varscan2
- FCGBP | c.12561G>A p.E4187= | Silent (SNP) | VAF 111/403 reads (28%) | called by muse, mutect2, varscan2
- FGA | c.312G>T p.S104= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs201709083, COSV57394298; called by muse, mutect2, varscan2
- FGF12 | c.732G>A p.*244= (on ENST00000454309 / NM_021032.5; = p.*182= on NM_004113.6) | Silent (SNP) | VAF 55/285 reads (19%) | catalogued as COSV53184452; called by muse, mutect2, varscan2
- FOCAD | c.1689T>A p.R563= | Silent (SNP) | VAF 37/233 reads (16%) | called by muse, mutect2, varscan2
- FOXG1 | c.378C>A p.G126= | Silent (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.870T>A p.G290= | Silent (SNP) | VAF 53/364 reads (15%) | called by muse, mutect2, varscan2
- GALNT12 | c.465A>C p.T155= | Silent (SNP) | VAF 38/305 reads (12%) | called by muse, mutect2, varscan2
- GRIK5 | c.2547G>C p.L849= | Silent (SNP) | VAF 101/414 reads (24%) | called by muse, mutect2, varscan2
- GRIK5 | c.1560G>T p.G520= | Silent (SNP) | VAF 58/252 reads (23%) | called by muse, mutect2, varscan2
- GZMB | c.252G>C p.P84= | Silent (SNP) | VAF 48/325 reads (15%) | catalogued as rs747427440, COSV99362176; called by muse, mutect2, varscan2
- HGS | c.1752G>A p.S584= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as rs762599320; called by muse, mutect2, varscan2
- HOMER3 | c.864C>T p.A288= | Silent (SNP) | VAF 31/236 reads (13%) | catalogued as rs754479036; called by muse, mutect2, varscan2
- HOXA2 | c.252G>T p.P84= | Silent (SNP) | VAF 30/168 reads (18%) | called by muse, mutect2, varscan2
- HS6ST1 | c.744C>T p.N248= | Silent (SNP) | VAF 81/403 reads (20%) | called by muse, mutect2, varscan2
- ILDR2 | c.1602G>A p.E534= | Silent (SNP) | VAF 47/187 reads (25%) | called by muse, mutect2, varscan2
- INTS7 | c.2292G>T p.R764= | Silent (SNP) | VAF 44/203 reads (22%) | called by muse, mutect2, varscan2
- IQCK | c.72C>T p.F24= | Silent (SNP) | VAF 130/444 reads (29%) | catalogued as rs760207487; called by muse, mutect2, varscan2
- IRX2 | c.726G>T p.P242= | Silent (SNP) | VAF 156/826 reads (19%) | catalogued as rs1163495134, COSV57410443, COSV57411404; called by muse, mutect2, varscan2
- ITGA11 | c.711A>T p.G237= | Silent (SNP) | VAF 71/267 reads (27%) | called by muse, mutect2, varscan2
- ITGA3 | c.156C>T p.F52= | Silent (SNP) | VAF 72/294 reads (24%) | called by muse, mutect2, varscan2
- ITPR3 | c.7044C>T p.L2348= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as rs1327332570; called by muse, varscan2
- KCNK5 | c.1113C>T p.S371= | Silent (SNP) | VAF 90/475 reads (19%) | called by muse, mutect2, varscan2
- KCNK5 | c.1002C>A p.L334= | Silent (SNP) | VAF 61/354 reads (17%) | called by muse, mutect2, varscan2
- KLHL17 | c.1116G>A p.V372= | Silent (SNP) | VAF 109/198 reads (55%) | catalogued as rs1193299794; called by muse, mutect2, varscan2
- LINS1 | c.747G>T p.L249= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- LRRC15 | c.363C>T p.F121= | Silent (SNP) | VAF 161/388 reads (41%) | called by muse, mutect2, varscan2
- MAP1S | c.1089G>A p.A363= | Silent (SNP) | VAF 102/561 reads (18%) | catalogued as rs1458602500; called by muse, mutect2, varscan2
- MFSD11 | c.948G>T p.L316= | Silent (SNP) | VAF 77/319 reads (24%) | catalogued as rs567649684; called by muse, mutect2, varscan2
- MROH2B | c.2385G>T p.L795= | Silent (SNP) | VAF 297/607 reads (49%) | called by muse, mutect2, varscan2
- MTRR | c.81G>A p.V27= | Silent (SNP) | VAF 142/792 reads (18%) | catalogued as rs1375881293; called by muse, varscan2
- MYO1A | c.2682G>A p.L894= | Silent (SNP) | VAF 57/540 reads (11%) | called by muse, mutect2, varscan2
- MYO9B | c.5967A>T p.P1989= | Silent (SNP) | VAF 60/184 reads (33%) | called by muse, mutect2, varscan2
- MYOD1 | c.363C>A p.R121= | Silent (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- MYOT | c.291C>T p.L97= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as rs1315728430, COSV99525151; called by muse, mutect2, varscan2
- NIFK | c.21G>T p.P7= | Silent (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- NOX3 | c.18T>A p.I6= | Silent (SNP) | VAF 55/260 reads (21%) | called by muse, mutect2, varscan2
- NUDT19 | c.864G>T p.L288= | Silent (SNP) | VAF 116/461 reads (25%) | catalogued as COSV67959761; called by muse, mutect2, varscan2
- NXPE1 | c.309C>A p.A103= | Silent (SNP) | VAF 59/245 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.8178G>T p.R2726= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- OR14A16 | c.603T>C p.N201= | Silent (SNP) | VAF 47/241 reads (20%) | catalogued as rs763860267; called by muse, mutect2, varscan2
- OR4F15 | c.585G>T p.L195= | Silent (SNP) | VAF 45/333 reads (14%) | called by muse, mutect2, varscan2
- OR5D14 | c.222T>C p.C74= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV59458079; called by muse, mutect2, varscan2
- OTOG | c.5613G>C p.A1871= | Silent (SNP) | VAF 30/486 reads (6%) | called by muse, mutect2
- OTOP1 | c.1350G>A p.E450= | Silent (SNP) | VAF 47/420 reads (11%) | called by muse, mutect2, varscan2
- PCARE | c.1083G>T p.S361= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as COSV59053751; called by muse, mutect2, varscan2
- PLD5 | c.777G>T p.L259= (on ENST00000442594; = p.L197= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/281 reads (20%) | catalogued as COSV59141953; called by muse, mutect2, varscan2
- PLEKHN1 | c.1137C>T p.A379= (on ENST00000379409; = p.A327= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs375145822; called by muse, mutect2, varscan2
- POU3F2 | c.1177C>T p.L393= | Silent (SNP) | VAF 47/200 reads (24%) | called by muse, mutect2, varscan2
- PPM1K | c.666G>C p.L222= | Silent (SNP) | VAF 88/246 reads (36%) | called by muse, varscan2
- PPP1R15B | c.225C>G p.P75= | Silent (SNP) | VAF 127/519 reads (24%) | called by muse, mutect2, varscan2
- PRADC1 | c.33C>T p.L11= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as rs1163996607; called by muse, mutect2, varscan2
- PRAMEF17 | c.490C>T p.L164= | Silent (SNP) | VAF 54/499 reads (11%) | catalogued as rs768301704; called by muse, mutect2, varscan2
- PREX1 | c.4578G>C p.A1526= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- PRKG1 | c.612C>T p.L204= | Silent (SNP) | VAF 59/238 reads (25%) | called by muse, mutect2, varscan2
- PRSS56 | c.669C>A p.T223= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99286103; called by muse, mutect2, varscan2
- RAP1GDS1 | c.783G>T p.L261= (on ENST00000408927 / NM_001100427.2; = p.L262= on NM_021159.5) | Silent (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- REG1A | c.378T>A p.I126= | Silent (SNP) | VAF 52/332 reads (16%) | called by muse, mutect2, varscan2
- RGL3 | c.651T>G p.V217= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- RGL4 | c.810C>T p.F270= | Silent (SNP) | VAF 172/668 reads (26%) | called by muse, mutect2, varscan2
- RGS20 | c.117C>T p.H39= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as rs1325925092; called by muse, mutect2, varscan2
- RSPH3 | c.354G>T p.G118= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- SCN1B | c.609C>T p.I203= | Silent (SNP) | VAF 57/486 reads (12%) | called by muse, mutect2, varscan2
- SH3BP4 | c.753C>T p.S251= | Silent (SNP) | VAF 99/416 reads (24%) | catalogued as rs1301750735; called by muse, mutect2, varscan2
- SHANK1 | c.4848C>A p.T1616= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs754989962; called by muse, mutect2, varscan2
- SLC15A5 | c.1176T>A p.L392= | Silent (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2
- SLC22A24 | c.309G>T p.G103= | Silent (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- SLC25A3 | c.78C>G p.L26= | Silent (SNP) | VAF 94/388 reads (24%) | called by muse, varscan2
- SLC29A3 | c.765G>A p.E255= | Silent (SNP) | VAF 34/287 reads (12%) | catalogued as rs1305552084; called by muse, mutect2, varscan2
- SLC4A1 | c.2148C>G p.A716= | Silent (SNP) | VAF 102/359 reads (28%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1111C>T p.L371= | Silent (SNP) | VAF 56/242 reads (23%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2769C>G p.V923= | Silent (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2991C>G p.P997= | Silent (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- SRRM2 | c.4437A>G p.E1479= | Silent (SNP) | VAF 85/300 reads (28%) | called by muse, mutect2, varscan2
- STAP2 | c.633C>T p.P211= | Silent (SNP) | VAF 115/475 reads (24%) | catalogued as rs781039850; called by muse, mutect2, varscan2
- STK31 | c.33C>T p.S11= | Silent (SNP) | VAF 44/357 reads (12%) | catalogued as rs776358668, COSV63455581, COSV63455969; called by muse, mutect2, varscan2
- STRADB | c.162C>T p.N54= | Silent (SNP) | VAF 64/301 reads (21%) | catalogued as rs773980693; called by muse, mutect2, varscan2
- STXBP2 | c.612C>G p.A204= | Silent (SNP) | VAF 145/575 reads (25%) | called by muse, mutect2, varscan2
- SUPT20H | c.1341C>T p.T447= (on ENST00000350612 / NM_001014286.3; = p.T448= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1379900712; called by muse, mutect2, varscan2
- SYT4 | c.1047C>T p.T349= | Silent (SNP) | VAF 113/432 reads (26%) | catalogued as rs372129860, COSV54905048; called by muse, mutect2, varscan2
- TAAR1 | c.105G>A p.L35= | Silent (SNP) | VAF 53/263 reads (20%) | catalogued as COSV51588996; called by muse, mutect2, varscan2
- TAS2R3 | c.225A>G p.T75= | Silent (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- TBX22 | c.16C>A p.R6= | Silent (SNP) | VAF 116/276 reads (42%) | catalogued as COSV64785837, COSV64785955; called by muse, mutect2, varscan2
- TDRD9 | c.3144G>A p.V1048= | Silent (SNP) | VAF 119/387 reads (31%) | catalogued as COSV59143769; called by muse, mutect2, varscan2
- TENM2 | c.5490C>A p.G1830= (on ENST00000518659 / NM_001122679.2; = p.G1591= on NM_001080428.3) | Silent (SNP) | VAF 53/188 reads (28%) | called by muse, mutect2, varscan2
- THAP12 | c.2043G>T p.L681= | Silent (SNP) | VAF 57/207 reads (28%) | called by muse, mutect2, varscan2
- TLN2 | c.90G>C p.A30= | Silent (SNP) | VAF 36/374 reads (10%) | catalogued as COSV60891683; called by muse, mutect2
- TLX3 | c.522C>A p.S174= | Silent (SNP) | VAF 131/410 reads (32%) | called by muse, mutect2, varscan2
- TMEM132D | c.3036C>T p.I1012= | Silent (SNP) | VAF 43/399 reads (11%) | catalogued as COSV67159948; called by muse, mutect2, varscan2
- TMPRSS9 | c.2091C>T p.N697= (on ENST00000648592; = p.N663= on NM_182973.2) | Silent (SNP) | VAF 17/531 reads (3%) | called by muse, mutect2
- TNN | c.1767C>A p.G589= | Silent (SNP) | VAF 93/543 reads (17%) | called by muse, mutect2, varscan2
- TRIM24 | c.1173T>A p.R391= | Silent (SNP) | VAF 72/301 reads (24%) | catalogued as COSV58971805; called by muse, mutect2, varscan2
- TRIM62 | c.735G>T p.L245= | Silent (SNP) | VAF 87/182 reads (48%) | catalogued as COSV52223982; called by muse, mutect2, varscan2
- TSHZ1 | c.2289C>A p.P763= (on ENST00000580243 / NM_001308210.2; = p.P718= on NM_005786.6) | Silent (SNP) | VAF 91/333 reads (27%) | called by muse, mutect2, varscan2
- TTLL3 | c.2004A>G p.Q668= | Silent (SNP) | VAF 56/226 reads (25%) | catalogued as rs762331275; called by muse, mutect2, varscan2
- TTN | c.39906A>G p.E13302= (on ENST00000591111; = p.E5878= on NM_003319.4) | Silent (SNP) | VAF 31/476 reads (7%) | called by muse, mutect2
- VEZT | c.405A>G p.T135= | Silent (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- VGF | c.105C>A p.L35= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- VPS9D1 | c.330A>T p.R110= | Silent (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- VSTM2B | c.657G>C p.A219= | Silent (SNP) | VAF 43/416 reads (10%) | called by muse, mutect2, varscan2
- WDR72 | c.1488C>A p.I496= | Silent (SNP) | VAF 43/444 reads (10%) | catalogued as rs541688639, COSV100854959, COSV64741725; called by muse, mutect2
- WNT9B | c.10C>A p.R4= | Silent (SNP) | VAF 86/357 reads (24%) | called by muse, mutect2, varscan2
- ZBTB11 | c.1980A>G p.L660= | Silent (SNP) | VAF 95/443 reads (21%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.1389C>G p.L463= | Silent (SNP) | VAF 90/318 reads (28%) | called by muse, mutect2, varscan2
- ZNF333 | c.1734G>A p.R578= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- ZNF488 | c.456C>A p.P152= | Silent (SNP) | VAF 65/529 reads (12%) | called by muse, mutect2, varscan2
- ZNF585A | c.1194A>T p.T398= (on ENST00000292841 / NM_001288800.2; = p.T343= on NM_152655.3) | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as COSV53065366; called by muse, mutect2, varscan2
- ZNF606 | c.2106T>C p.H702= | Silent (SNP) | VAF 39/316 reads (12%) | called by muse, mutect2, varscan2
- AC023469.1 | n.315T>C | RNA (SNP) | VAF 30/219 reads (14%) | called by muse, mutect2, varscan2
- AC068631.2 | c.452-51A>G | Intron (SNP) | VAF 117/554 reads (21%) | called by muse, mutect2, varscan2
- AC093525.2 | c.*482T>G | 3'UTR (SNP) | VAF 12/289 reads (4%) | called by muse, mutect2
- ADAM22 | c.-16G>T | 5'UTR (SNP) | VAF 39/263 reads (15%) | catalogued as rs1209325150; called by muse, mutect2, varscan2
- AK9 | c.3633+477A>T | Intron (SNP) | VAF 51/236 reads (22%) | called by muse, varscan2
- AL121899.2 | c.*298G>T | 3'UTR (SNP) | VAF 44/317 reads (14%) | called by muse, mutect2, varscan2
- AL121899.2 | c.*299G>A | 3'UTR (SNP) | VAF 46/321 reads (14%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852615 A>G | 3'Flank (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- APOO | c.*16G>T | 3'UTR (SNP) | VAF 65/122 reads (53%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-459G>T | Intron (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2
- ASIC2 | c.556-179628C>T | Intron (SNP) | VAF 46/255 reads (18%) | catalogued as rs375042102; called by muse, mutect2, varscan2
- ATP8B2 | c.1342+118G>C | Intron (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- BCAR1 | c.12+3342_12+3357del | Intron (DEL) | VAF 43/290 reads (15%) | called by mutect2, pindel
- C1orf112 | c.*804C>T | 3'UTR (SNP) | VAF 55/236 reads (23%) | catalogued as rs763744922; called by muse, mutect2, varscan2
- C3 | c.2246-16T>C | Intron (SNP) | VAF 56/437 reads (13%) | called by muse, mutect2, varscan2
- C4orf50 | c.-1241C>T | 5'UTR (SNP) | VAF 29/266 reads (11%) | catalogued as rs1197205188; called by muse, mutect2, varscan2
- CACNA1C | chr12:2053557 T>C | 5'Flank (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CCDC74B | c.296-44C>T | Intron (SNP) | VAF 67/312 reads (21%) | catalogued as rs554327340; called by muse, mutect2, varscan2
- CDH15 | chr16:89168547 A>G | 5'Flank (SNP) | VAF 46/263 reads (17%) | catalogued as rs1322141886; called by muse, mutect2, varscan2
- CIT | c.4729-425A>G | Intron (SNP) | VAF 82/315 reads (26%) | catalogued as rs763382673; called by muse, mutect2, varscan2
- CLPB | c.456-5119A>G | Intron (SNP) | VAF 34/339 reads (10%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1898-231G>T | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- COL4A3 | c.2746+24A>C | Intron (SNP) | VAF 87/370 reads (24%) | called by muse, varscan2
- CREBBP | c.-102G>T | 5'UTR (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2
- DENND5B | c.128-3705G>T | Intron (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- DLX1 | c.513+58C>A | Intron (SNP) | VAF 52/234 reads (22%) | called by mutect2, varscan2
- DNM2 | c.1336-981del | Intron (DEL) | VAF 77/587 reads (13%) | called by mutect2, pindel, varscan2
- DUX4L8 | n.708C>A | RNA (SNP) | VAF 63/264 reads (24%) | called by muse, mutect2, varscan2
- ELFN1 | c.-456+5424G>T | Intron (SNP) | VAF 71/473 reads (15%) | called by muse, mutect2, varscan2
- ERBB4 | c.1872-158G>C | Intron (SNP) | VAF 74/455 reads (16%) | catalogued as COSV99634934; called by muse, mutect2, varscan2
- EXOC4 | c.1418-53226A>G | Intron (SNP) | VAF 25/162 reads (15%) | called by muse, mutect2, varscan2
- FASTKD1 | c.2188+32C>T | Intron (SNP) | VAF 47/264 reads (18%) | called by muse, mutect2, varscan2
76 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 76 other) are not listed here.
